CCDI case PBCNRT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/5923b19c-8b07-4a01-aeed-ee110aab620c

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 16.7 years (6,112 days).

Biospecimens (4 samples)
- Samples 0DWERP, 0DWES7, 0DWODU (3 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWERY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
